Somatic mutation profile of tumor specimen ALCH-AESK-TTP1-A (aliquot ALCH-AESK-TTP1-A-1-0-D-A673-36) from ALCHEMIST case ALCH-AESK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.0 years (25,192 days).
Specimen ALCH-AESK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d929031-9bd3-4522-9975-17b6cffaf31b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AESK-NB1-A (Blood Derived Normal), aliquot ALCH-AESK-NB1-A-1-0-D-A673-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccc0a3eb-b9ea-4582-a5ce-a260f1608d8b

The open-access MAF lists 103 somatic variants for this specimen: 66 protein-altering or splice-affecting, 30 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 30, Nonsense Mutation 5, Intron 5, Splice Region 4, Translation Start Site 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 42/542 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.396G>C p.K132N | Missense Mutation (SNP) | VAF 46/340 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866775781, COSV52688381, COSV52705927, COSV52891203, COSV53339296; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- AGAP6 | c.601A>T p.T201S (on ENST00000374056 / NM_001365867.1; = p.T224S on NM_001077665.2) | Missense Mutation (SNP) | VAF 52/1012 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.467); catalogued as rs1423023221; called by muse, mutect2
- AMBRA1 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.232); catalogued as rs1384613272, COSV54050101; called by muse, mutect2
- CALCRL | c.17C>A p.T6N | Missense Mutation (SNP) | VAF 24/364 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as COSV66476839, COSV66477899; called by muse, mutect2
- CCDC47 | c.607C>T p.H203Y | Missense Mutation (SNP) | VAF 34/455 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as COSV56722487; called by muse, mutect2
- CDH6 | c.382G>C p.A128P | Missense Mutation (SNP) | VAF 51/506 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99418966; called by muse, mutect2, varscan2
- DGKB | c.2041C>G p.R681G | Missense Mutation (SNP) | VAF 14/307 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); catalogued as COSV51761564, COSV51781556; called by muse, mutect2
- DNAH6 | c.1485G>T p.K495N | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV99408525; called by muse, mutect2
- ENG | c.278G>T p.R93L | Missense Mutation (SNP) | VAF 26/472 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as rs532649202; called by muse, mutect2
- EPHA1 | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs756203512, COSV51973676; called by muse, mutect2
- FLG | c.1397G>C p.G466A | Missense Mutation (SNP) | VAF 30/456 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.952); catalogued as COSV64236425, COSV64244942; called by muse, mutect2
- KIAA1549L | c.2381G>T p.R794L (on ENST00000321505; = p.R1091L on NM_012194.3) | Missense Mutation (SNP) | VAF 16/430 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1319585370, COSV55772245; called by muse, mutect2
- KIR3DL1 | c.89T>C p.F30S | Missense Mutation (SNP) | VAF 16/426 reads (4%) | SIFT tolerated (0.8); PolyPhen benign (0.012); catalogued as rs770048175; called by muse, mutect2
- LRIG3 | c.74G>A p.G25D | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.706); catalogued as rs766115590; called by muse, mutect2
- MYO5A | c.3682G>A p.A1228T | Missense Mutation (SNP) | VAF 33/440 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs1226097359; called by muse, mutect2
- OR2Z1 | c.376G>T p.V126L | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV100136474; called by muse, mutect2
- RASA2 | c.2534T>C p.V845A | Missense Mutation (SNP) | VAF 11/320 reads (3%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.255); catalogued as rs1171272275; called by muse, mutect2
- RHBG | c.978G>A p.T326= | Splice Region (SNP) | VAF 30/330 reads (9%) | catalogued as rs140066954; called by muse, mutect2
- RIMS2 | c.4061C>T p.T1354M | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs374240612; called by muse, mutect2
- ROBO2 | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 15/406 reads (4%) | catalogued as COSV59911254; called by muse, mutect2
- RSPH4A | c.2038G>T p.D680Y | Missense Mutation (SNP) | VAF 20/534 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1289146333; called by muse, mutect2
- SHOX | c.317C>A p.S106* | Nonsense Mutation (SNP) | VAF 32/376 reads (9%) | catalogued as COSV61860752; called by muse, mutect2
- TERT | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.113); catalogued as rs200843534, COSV57220010; ClinVar: uncertain significance; called by mutect2, varscan2
- ADGRF2 | c.433G>T p.D145Y (on ENST00000296862 / NM_001368115.2; = p.D77Y on NM_153839.7) | Missense Mutation (SNP) | VAF 28/528 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- ANKLE2 | c.2522C>T p.A841V | Missense Mutation (SNP) | VAF 36/400 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ATMIN | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- BRSK2 | c.1225A>T p.R409W | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2
- CDH10 | c.415C>A p.P139T | Missense Mutation (SNP) | VAF 31/603 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2
- CEBPB | c.198C>G p.I66M | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2
- CILP2 | c.1921G>T p.G641C | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COIL | c.607C>G p.P203A | Missense Mutation (SNP) | VAF 30/307 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.015); called by muse, mutect2
- CSMD3 | c.10988C>A p.T3663K (on ENST00000297405 / NM_001363185.1; = p.T3494K on NM_052900.3) | Missense Mutation (SNP) | VAF 191/810 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- DNAH8 | c.9523A>G p.K3175E | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); called by muse, mutect2
- ELF1 | c.927G>C p.E309D | Missense Mutation (SNP) | VAF 24/644 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.022); called by muse, mutect2
- FAM53C | c.716C>G p.P239R | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.667); called by muse, mutect2
- FNTB | c.113A>T p.D38V | Missense Mutation (SNP) | VAF 20/342 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.328); called by muse, mutect2
- GRPR | c.792G>C p.K264N | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- GUCY2F | c.946G>A p.V316M | Missense Mutation (SNP) | VAF 17/229 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.015); called by muse, mutect2
- GXYLT1 | c.1228G>T p.V410L | Missense Mutation (SNP) | VAF 26/372 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.04); called by muse, mutect2
- IPO9 | c.958G>A p.V320M | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.366); called by muse, mutect2
- KCNK2 | c.45A>T p.G15= | Splice Region (SNP) | VAF 20/360 reads (6%) | called by muse, mutect2
- KDM5D | c.2329C>T p.R777C | Missense Mutation (SNP) | VAF 65/380 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MARCO | c.1036G>A p.G346S | Missense Mutation (SNP) | VAF 24/307 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MLXIP | c.2385C>T p.I795= | Splice Region (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2, varscan2
- MON2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 8/202 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.584); called by muse, mutect2
- MYOF | c.3233G>C p.R1078T | Missense Mutation (SNP) | VAF 20/460 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2
- NAT8 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2
- NGEF | c.1047T>A p.C349* | Nonsense Mutation (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- PLPPR4 | c.1613A>T p.E538V | Missense Mutation (SNP) | VAF 27/247 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM26 | c.1952C>T p.A651V (on ENST00000438737 / NM_001366735.2; = p.A648V on NM_022118.5) | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RNF213 | c.8162T>A p.L2721H | Missense Mutation (SNP) | VAF 44/664 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- RPE65 | c.221A>G p.E74G | Missense Mutation (SNP) | VAF 21/767 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2
- SCHIP1 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 23/254 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2
- SETBP1 | c.2519C>T p.S840L | Missense Mutation (SNP) | VAF 22/712 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- SSX2IP | c.672A>C p.I224= | Splice Region (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2
- SYT10 | c.533T>G p.L178R | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2
- TNPO2 | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 7/181 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- TUBB | c.467G>C p.R156P | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2
- UNC13B | c.236G>A p.W79* | Nonsense Mutation (SNP) | VAF 24/368 reads (7%) | called by muse, mutect2
- UNC5D | c.1763C>A p.P588H | Missense Mutation (SNP) | VAF 14/361 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.482); called by muse, mutect2
- USP9X | c.4129A>T p.T1377S | Missense Mutation (SNP) | VAF 39/295 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFHX4 | c.1906C>T p.H636Y | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, varscan2
- ZNF334 | c.1102C>T p.Q368* | Nonsense Mutation (SNP) | VAF 11/248 reads (4%) | called by muse, mutect2
- ZNF850 | c.883A>T p.T295S | Missense Mutation (SNP) | VAF 65/382 reads (17%) | SIFT tolerated (0.99); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- ZNF850 | c.127C>A p.L43M | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.849); called by muse, mutect2
- AHNAK | c.13362C>T p.I4454= | Silent (SNP) | VAF 26/400 reads (7%) | catalogued as COSV57206488; called by muse, mutect2
- AMER1 | c.270C>T p.L90= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs148294124, COSV100366611; called by muse, mutect2, varscan2
- ANKRD36C | c.2646T>C p.S882= | Silent (SNP) | VAF 16/511 reads (3%) | called by muse, mutect2
- ASAP3 | c.153C>T p.I51= | Silent (SNP) | VAF 15/241 reads (6%) | called by muse, mutect2
- ATP11A | c.1068T>C p.F356= | Silent (SNP) | VAF 16/544 reads (3%) | catalogued as rs1191802574; called by muse, mutect2
- BCHE | c.738C>T p.T246= | Silent (SNP) | VAF 14/324 reads (4%) | catalogued as rs1208573559, COSV100011883; called by muse, mutect2
- BRINP3 | c.1338C>G p.A446= | Silent (SNP) | VAF 13/405 reads (3%) | catalogued as COSV100819450; called by muse, mutect2
- C2CD2L | c.57C>T p.F19= | Silent (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- CCR4 | c.237C>G p.L79= | Silent (SNP) | VAF 14/362 reads (4%) | called by muse, mutect2
- GRIK5 | c.2832C>T p.A944= | Silent (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- HNF1A | c.1242C>T p.I414= | Silent (SNP) | VAF 16/234 reads (7%) | called by muse, mutect2
- KNOP1 | c.591G>T p.G197= | Silent (SNP) | VAF 14/230 reads (6%) | called by muse, mutect2
- KRTAP11-1 | c.81C>G p.T27= | Silent (SNP) | VAF 21/240 reads (9%) | called by muse, mutect2
- LETMD1 | c.876G>A p.K292= | Silent (SNP) | VAF 20/674 reads (3%) | called by muse, mutect2
- LRP1B | c.5031G>A p.V1677= | Silent (SNP) | VAF 16/367 reads (4%) | called by muse, mutect2
- MAGEE1 | c.630C>G p.T210= | Silent (SNP) | VAF 11/105 reads (10%) | called by muse, mutect2, varscan2
- OR2A25 | c.606A>T p.A202= | Silent (SNP) | VAF 24/672 reads (4%) | called by muse, mutect2
- OR5D16 | c.849G>T p.V283= | Silent (SNP) | VAF 23/652 reads (4%) | catalogued as COSV101004002, COSV65722367; called by muse, mutect2
- PLXNA2 | c.1836C>A p.I612= | Silent (SNP) | VAF 32/340 reads (9%) | called by muse, mutect2
- RAD9B | c.213G>A p.V71= | Silent (SNP) | VAF 30/504 reads (6%) | called by muse, mutect2
- RNF213 | c.3429A>G p.R1143= | Silent (SNP) | VAF 25/396 reads (6%) | called by muse, mutect2
- RUSF1 | c.879G>T p.R293= | Silent (SNP) | VAF 16/258 reads (6%) | called by muse, mutect2
- SCYL3 | c.1563A>G p.S521= (on ENST00000367770; = p.S467= on NM_020423.7) | Silent (SNP) | VAF 50/362 reads (14%) | called by muse, mutect2, varscan2
- SFTPB | c.864G>A p.P288= | Silent (SNP) | VAF 44/556 reads (8%) | catalogued as rs772068983, COSV100667140; called by muse, mutect2
- SLC22A11 | c.60G>A p.Q20= | Silent (SNP) | VAF 12/106 reads (11%) | called by muse, varscan2
- SLC9A4 | c.1251C>T p.S417= | Silent (SNP) | VAF 68/597 reads (11%) | catalogued as COSV54837466; called by muse, mutect2, varscan2
- SLFNL1 | c.216G>A p.E72= | Silent (SNP) | VAF 26/284 reads (9%) | called by muse, mutect2
- STK32C | c.864G>T p.L288= | Silent (SNP) | VAF 5/34 reads (15%) | called by muse, varscan2
- SVEP1 | c.1701C>T p.I567= | Silent (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- WASHC2A | c.246C>G p.V82= | Silent (SNP) | VAF 19/536 reads (4%) | called by muse, mutect2
- AC235097.1 | n.289G>T | RNA (SNP) | VAF 16/216 reads (7%) | called by muse, mutect2
- ANO1 | c.1951-34C>G | Intron (SNP) | VAF 13/227 reads (6%) | catalogued as rs1200333499; called by muse, mutect2
- CD209 | c.47-12C>G | Intron (SNP) | VAF 12/311 reads (4%) | called by muse, mutect2
- CIC | chr19:42284655 C>T | 5'Flank (SNP) | VAF 12/117 reads (10%) | called by muse, mutect2
- CYP24A1 | c.449+47C>A | Intron (SNP) | VAF 22/210 reads (10%) | catalogued as rs1195705530; called by muse, mutect2
- PHKA1 | c.3072+2165C>G | Intron (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
- SMARCB1 | c.363-2142C>G | Intron (SNP) | VAF 12/414 reads (3%) | called by muse, mutect2
